Gene-level copy-number profile of tumor specimen ALCH-AEOA-TTP1-A from ALCHEMIST case ALCH-AEOA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.4 years (28,643 days).
Specimen ALCH-AEOA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6a1c8807-bf5a-4f3d-a287-a8ca1c63ad91.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEOA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/c1882bbf-06bd-459b-92ec-5622a74341f4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,024; copy number 1: 17,525; copy number 2: 34,624; copy number 3: 2,943; copy number 4: 2,101; copy number 5: 148; copy number 6: 13; copy number 7: 7; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 1,020 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:986,997–1,028,972, 3 genes (within-gene range 0–2): IDUA, FGFRL1, AC019103.1.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–1): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:2,493,876–27,589,073, 532 genes (broad region; genes not listed).
- chr8:27,633,868–27,703,789, 6 genes: SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:136,483,495–136,486,067, 1 gene (within-gene range 0–2): C9orf163.
- chr10:23,343,957–23,393,467, 2 genes (within-gene range 0–1): AL606469.1, AL606469.2.
- chr10:31,602,862–31,606,218, 1 gene: AL161935.1.
- chr10:37,775,371–37,859,110, 6 genes: AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1.
- chr11:55,602,360–55,607,645, 1 gene: OR4C11.
- chr13:34,910,545–34,928,076, 2 genes: Metazoa_SRP, AL138690.1.
- chr16:15,104,312–15,154,564, 5 genes (within-gene range 0–2): NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA.
- chr16:88,234,785–89,052,966, 32 genes: AC138512.1, ZNF469, ZFPM1, MIR5189, AC116552.1, ZC3H18, IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3, CTU2, AC138028.6, PIEZO1, MIR4722, AC138028.4, AC138028.2, AC138028.5, AC138028.1, CDT1, APRT, GALNS, TRAPPC2L, PABPN1L, CBFA2T3, AC092384.2, AC092384.3, AC092384.1, AC135782.2, AC135782.1.
- chr18:49,822,789–60,902,726, 171 genes (within-gene range 0–1) (broad region; genes not listed).
- chr18:61,571,342–70,491,205, 106 genes (broad region; genes not listed).
- chr18:70,630,534–80,247,514, 145 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 154 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–194,180, 8 genes, copy number 5 (within-gene range 3–5): AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3.
- chr7:32,580,949–32,761,787, 2 genes, copy number 5 (within-gene range 4–5): DPY19L1P1, ZNRF2P1.
- chr7:52,891,837–55,593,193, 37 genes, copy number 5–7: SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3.
- chr7:55,638,274–55,678,490, 3 genes, copy number 6: CDC42P2, TUBBP6, AC091812.1.
- chr7:56,408,699–63,368,156, 100 genes, copy number 5 (broad region; genes not listed).
- chr19:7,030,578–7,058,640, 4 genes, copy number 7–14: MBD3L5, MBD3L4, MBD3L2, MBD3L3.

Autosomal genes at a single copy (total copy number 1): 17,496. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
